Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3347, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3347-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Kidney, right, radical nephrectomy:
Renal cell carcinoma (see tumor characteristics).

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type
2. Tumor site: Right kidney, mid-portion.
3. Tumor size: 6.5 x 4 x 3.5 cm.
4. Macroscopic extent of tumor: Tumor extends into perirenal adipose tissue.
5. Nuclear grade: Fuhrman grade: 2 of 4.
6. Lymphovascular space invasion: Yes.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not involved by tumor; however, the perirenal adipose tissue demonstrates extension of tumor.

Surgical Margin Status:

1. Soft tissue margins: No evidence of malignancy.
2. Ureteral margin: No evidence of malignancy.
3. Vascular Margins: No evidence of malignancy.

Lymph Node Status:

1. Total number of lymph nodes examined: One (precaval - see part B).
2. Number of lymph nodes containing metastatic carcinoma: 1 of 1 (precaval) .

Other Significant Findings:

1. Other significant findings: In focal areas, the tumor cells demonstrate a spindle morphology, however, they still demonstrate clear cytoplasm and are therefore not interpreted as being sarcomatoid.
2. pTNM stage: pT3a N1 MX.

Staging sheet #18

B. Lymph node, precaval, excision:
Metastatic renal cell carcinoma infiltrating 1 of 1 lymph node.

[page 2 of 2]
Electronic Signature: [REDACTED]

COMMENTS:

A. For quality assurance, this case is reviewed by [REDACTED], who concurs with the diagnosis.

B. Although a lymph node dissection is not received, a single lymph node labeled 'precaval' is received in surgical pathology. This demonstrates metastatic renal cell carcinoma.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right kidney

B. Precaval lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled [REDACTED] and consists of a 158 gram right kidney measuring 10 x 6.5 x 3.8 cm in greatest dimension. The capsule is tan-gray, glistening and displaying an abundant amount of adherent adipose tissue as well as nodular mass in the mid-portion of the kidney. The superior pole also displays an orange brown firm adrenal gland, measuring 3.5 x 2.0 x 0.8 cm as well as a 0.6 cm. firm gray-tan nodule adjacent to it. The hilar region displays abundant adipose tissue with a portion of ureter measuring 4 cm in length and 0.8 cm in diameter. Bivalving the kidney reveals fat-filled calyces and blunted pyramids with a central tan yellow firm lobular mass, measuring 6.5 x 4.0 x 3.5 cm in greatest dimension. This mass does not appear to grossly invade the ureter or surrounding vessels. No other gross lesions are noted. Samples are taken for genomic studies. Representative samples are submitted in eight cassettes labeled [REDACTED] and are designated as follows:

Blood vessels and ureteral margin submitted as block 1; adrenal gland and adjacent gray-tan nodule 2; inked capsule 3; lesion 4-7; normal renal tissue 8.

B. Container B is labeled [REDACTED] and consists of a tan yellow rubbery firm nodule, 2.0 x 1.8 x 1.5 cm in greatest dimension. Samples of this nodule are submitted in two cassettes labeled [REDACTED].

[REDACTED]

Source: NCI Genomic Data Commons file feaa998b-edff-4c42-b636-731823225d78 (TCGA-A3-3347.3F843E1D-11A7-4103-8EF1-0F918DA1B60F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).